Surgical pathology report (de-identified scan), TCGA case TCGA-14-1823, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1823-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info:

TCGA-14-1823

* Final Report *

AP REPORT

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT OCCIPITAL LOBE, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. BRAIN, RIGHT OCCIPITAL LOBE, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).

SPECIMEN:

1. Right occipital brain lesion.
2. Right occipital brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Right occipital craniotomy; brain tumor.

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation, labeled with

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 2]
AP Report

* Final Report *

TCGA-14-1823

the patient's name, medical record number and as "right occipital brain lesion." It consists of multiple pieces of white-tan tissue measuring 0.8 x 0.5 x 0.2 cm. One third of the specimen is submitted for frozen section diagnosis and the remainder of the cryoblock is transferred to cassette "FS1A." The remaining tissue is entirely submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "right occipital brain lesion." It consists of multiple fragments of white-tan tissue measuring 2.0 x 1.4 x 0.5 cm in aggregate. The specimen is entirely submitted in cassettes "2A" and "2B."

INTRAOPERATIVE CONSULTATION:

FS1A: BRAIN, RIGHT OCCIPITAL LESION, BIOPSY (FROZEN SECTION): GLIOBLASTOMA.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

The pathologist has reviewed and interpreted the case with the resident/fellow.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 3
(Continued)

Source: NCI Genomic Data Commons file 02994501-d876-4782-b0a7-0f460e4469d0 (TCGA-14-1823.09E6A813-EB0D-4EBC-BF0C-95B9A0B9175B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).